Somatic mutation profile of tumor specimen C3L-00086-01 (aliquot CPT0092460009) from CPTAC case C3L-00086, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 56.9 years (20,790 days).
Specimen C3L-00086-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e33af275-332d-4031-8ea4-a023547ebe93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00086-31 (Blood Derived Normal), aliquot CPT0093790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfe66b09-b3b9-4252-a41d-e55508222039

The open-access MAF lists 594 somatic variants for this specimen: 391 protein-altering or splice-affecting, 121 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 252, Silent 121, Frame Shift Del 84, Intron 42, Nonsense Mutation 18, 3'UTR 15, Frame Shift Ins 14, 5'UTR 9, RNA 9, Splice Site 8, Splice Region 7, In Frame Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D2A | c.2773C>T p.R925* | Nonsense Mutation (SNP) | VAF 22/286 reads (8%) | catalogued as rs386833748, CM096680, COSV101052756; ClinVar: likely pathogenic; called by muse, mutect2
- GUSB | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 156/520 reads (30%) | catalogued as rs121918185, CM930359, COSV59222788; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 126/461 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 51/192 reads (27%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 381/674 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD097201, CM971271, COSV64288968, COSV64294667, COSV64296578, COSV64297040; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- TCF4 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 135/502 reads (27%) | catalogued as rs1131691735, CM120290, COSV61897774; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USP9X | c.7440dup p.A2481Sfs*17 | Frame Shift Ins (INS) | VAF 80/292 reads (27%) | catalogued as rs774054468; ClinVar: uncertain significance / not provided / pathogenic; called by mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 64/240 reads (27%) | catalogued as rs746497630; called by mutect2, varscan2
- ABCB6 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1335429025, COSV99521900; called by muse, mutect2, varscan2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 127/426 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACLY | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as rs1555633336; called by muse, mutect2, varscan2
- ADCY8 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV53912834; called by muse, mutect2, varscan2
- AMPH | c.1507del p.E503Kfs*3 | Frame Shift Del (DEL) | VAF 176/601 reads (29%) | catalogued as rs764644221; called by mutect2, pindel, varscan2
- ANGPTL7 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 164/554 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs924321890, COSV63869151; called by muse, mutect2, varscan2
- APBA1 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.335); catalogued as COSV55233361; called by muse, mutect2, varscan2
- ARNTL | c.180-3del | Splice Region (DEL) | VAF 101/344 reads (29%) | catalogued as rs1565123805; called by mutect2, varscan2
- ASXL1 | c.1979G>A p.G660D | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60121831; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | catalogued as rs746676748; called by mutect2, varscan2
- ATXN2L | c.3004del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs771612620; called by mutect2, pindel, varscan2
- AVPR1A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs576296040, COSV54546387; called by muse, mutect2, varscan2
- B3GNT4 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV57337197; called by muse, mutect2, varscan2
- BEST2 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778596981; called by muse, mutect2, varscan2
- BMP4 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as CM1313121; called by muse, mutect2, varscan2
- BRCA1 | c.2825C>T p.A942V | Missense Mutation (SNP) | VAF 142/518 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as COSV58787472; called by muse, mutect2, varscan2
- BRD9 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs753813330, COSV100057422; called by muse, mutect2, varscan2
- BRICD5 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs145075016; called by muse, mutect2, varscan2
- BRIP1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs769573395; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BTBD8 | c.4651C>T p.R1551* (on ENST00000636805 / NM_001376131.1; = p.R1038* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 60/241 reads (25%) | catalogued as COSV64885534; called by muse, mutect2, varscan2
- C16orf90 | c.364C>T p.R122C (on ENST00000399645 / NM_001353385.2; = p.R113C on NM_001080524.2) | Missense Mutation (SNP) | VAF 72/489 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs540246037; called by muse, mutect2, varscan2
- C1orf116 | c.929G>A p.S310N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1558043669; called by muse, mutect2, varscan2
- CACFD1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs146555731; called by muse, mutect2, varscan2
- CACNA1C | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.928); catalogued as rs757507674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALCR | c.1076A>G p.K359R (on ENST00000649521 / NM_001164737.2; = p.K343R on NM_001742.4) | Missense Mutation (SNP) | VAF 132/438 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs764416704; called by muse, mutect2, varscan2
- CAPN1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs1456786646; called by muse, mutect2, varscan2
- CAPN15 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1303158417; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CCDC74B | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as rs149078598; called by muse, mutect2, varscan2
- CDH24 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 48/188 reads (26%) | catalogued as rs199667974; called by muse, mutect2, varscan2
- CEP290 | c.7263dup p.E2422* | Frame Shift Ins (INS) | VAF 79/320 reads (25%) | catalogued as rs1219184437; called by mutect2, pindel, varscan2
- CHD7 | c.5532C>T p.D1844= | Splice Region (SNP) | VAF 54/193 reads (28%) | catalogued as rs368279646; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRDL2 | c.84C>T p.R28= | Splice Region (SNP) | VAF 48/161 reads (30%) | catalogued as rs1184881606; called by muse, mutect2, varscan2
- CLASP2 | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56283493; called by muse, mutect2
- CLCN1 | c.132del p.H44Qfs*33 | Frame Shift Del (DEL) | VAF 73/268 reads (27%) | catalogued as COSV58370371; called by mutect2, pindel, varscan2
- CNTNAP2 | c.2862G>T p.K954N | Missense Mutation (SNP) | VAF 23/635 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV100667678; called by muse, mutect2
- COLEC12 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as rs921900714; called by muse, mutect2, varscan2
- COPB1 | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs1281082332; called by muse, mutect2, varscan2
- CPEB1 | c.685C>T p.R229C (on ENST00000617958; = p.R169C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs762664847, COSV55618480; called by muse, mutect2, varscan2
- CTC1 | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs532454635; called by muse, mutect2, varscan2
- CUX2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs775532302; called by muse, mutect2, varscan2
- CWC25 | c.521dup p.E175Gfs*16 | Frame Shift Ins (INS) | VAF 84/292 reads (29%) | catalogued as rs1318048628; called by mutect2, varscan2
- CXCL2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.198); catalogued as rs892211709; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | catalogued as rs766714372; called by mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, varscan2
- DOCK3 | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as COSV56519321; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | catalogued as rs782552436; called by mutect2, pindel
- DOCK8 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 132/547 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.222); catalogued as rs756970432; called by muse, mutect2, varscan2
- DSG2 | c.3226G>A p.V1076M | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV55202332; called by muse, mutect2, varscan2
- DTNA | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs768575898, COSV99310706; called by muse, mutect2, varscan2
- EFCAB14 | c.1132A>G p.S378G | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs759848365; called by muse, mutect2, varscan2
- ELAC1 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs776088986, COSV53997078; called by muse, mutect2, varscan2
- ELANE | c.67+1del | Frame Shift Del (DEL) | VAF 58/454 reads (13%) | catalogued as rs886039350; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- EMB | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); catalogued as rs750541683; called by muse, varscan2
- ERBB3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 89/345 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.341); catalogued as rs1324972550, COSV57259152; called by muse, varscan2
- FAM171A2 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1309192527; called by muse, mutect2
- FAM186B | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | catalogued as rs200005083, COSV57720382; called by muse, mutect2, varscan2
- FAM20C | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs755764751; called by muse, mutect2, varscan2
- FAM83H | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 11/228 reads (5%) | catalogued as rs1554622357; called by muse, mutect2
- FBN1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as CM054710, COSV100356016; called by muse, varscan2
- FBN3 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as COSV99561288; called by muse, mutect2, varscan2
- FCSK | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 125/465 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs528370718; called by muse, mutect2, varscan2
- FRAS1 | c.5011C>T p.Q1671* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as rs746031442; called by muse, mutect2
- FREM2 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs367642497; called by muse, mutect2, varscan2
- FRG1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 21/389 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs75585360, COSV56995045; called by muse, mutect2
- FTSJ3 | c.1035_1037del p.E345del | In Frame Del (DEL) | VAF 89/354 reads (25%) | catalogued as rs1372096209; called by pindel, varscan2
- FXR1 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs1417565250, COSV59763204; called by muse, mutect2
- GABRR2 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as rs746182488, COSV68764567; called by muse, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 48/222 reads (22%) | catalogued as rs780374709; called by mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | catalogued as rs763147690; called by mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 46/159 reads (29%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GTF2IRD2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as rs587627714, COSV63100466; called by muse, mutect2, varscan2
- HBB | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 141/553 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs33993568, CM024480, CM077191; ClinVar: benign; called by muse, mutect2, varscan2
- HEATR6 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 127/477 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs371368780; called by muse, mutect2, varscan2
- HIC1 | c.353T>C p.V118A (on ENST00000322941 / NM_001098202.1; = p.V99A on NM_006497.4) | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs1318583081, COSV53966371; called by muse, mutect2, varscan2
- HIVEP1 | c.6728C>T p.T2243M | Missense Mutation (SNP) | VAF 126/389 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs199539440; called by muse, mutect2, varscan2
- HLA-C | c.950T>G p.V317G | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs1289588842; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as COSV99670288; called by mutect2, pindel, varscan2
- HOXB2 | c.272del p.P91Rfs*8 | Frame Shift Del (DEL) | VAF 60/226 reads (27%) | catalogued as rs761024113; called by mutect2, pindel, varscan2
- HRNR | c.2243T>C p.L748S | Missense Mutation (SNP) | VAF 164/527 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs745660593, COSV64263050; called by muse, mutect2, varscan2
- HTR1F | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as rs377109125; called by muse, mutect2, varscan2
- HTT | c.8995G>A p.G2999R | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752320329, COSV100750514, COSV100751316; called by muse, mutect2, varscan2
- HYDIN | c.6772C>T p.R2258W | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751267096, COSV99992109; called by muse, mutect2, varscan2
- IFI6 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.419); catalogued as COSV59270214; called by muse, mutect2, varscan2
- IFT140 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs749432087; called by muse, mutect2, varscan2
- IGSF10 | c.5642G>A p.G1881D | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477022137; called by muse, mutect2, varscan2
- IGSF9B | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs267602785; called by muse, mutect2, varscan2
- IL21R | c.1549del p.R517Gfs*38 | Frame Shift Del (DEL) | VAF 44/191 reads (23%) | catalogued as rs748992699; called by mutect2, pindel, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 31/125 reads (25%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGA2B | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 92/324 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99289300; called by muse, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- KALRN | c.5135G>A p.R1712Q | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs369690103, COSV62564360; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs1159900432; called by mutect2, pindel, varscan2
- KIF26A | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs200286274; called by muse, mutect2, varscan2
- KMT2D | c.11714_11716dup p.Q3905dup | In Frame Ins (INS) | VAF 32/176 reads (18%) | catalogued as rs944680171; called by mutect2, varscan2
- KMT2D | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 84/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56426186; called by muse, mutect2, varscan2
- KRTAP10-8 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 58/567 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs782320802; called by muse, mutect2, varscan2
- LGR6 | c.1244C>A p.P415H (on ENST00000367278 / NM_001017403.1; = p.P363H on NM_021636.3) | Missense Mutation (SNP) | VAF 91/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99706255, COSV99706353; called by muse, mutect2, varscan2
- LGSN | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs765583125, COSV101040285; called by muse, mutect2, varscan2
- LPA | c.5288C>T p.A1763V | Missense Mutation (SNP) | VAF 115/441 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as rs371978511; called by muse, mutect2, varscan2
- LYPD2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs765524289, COSV63649659; called by muse, mutect2, varscan2
- MAGI2 | c.2064G>A p.W688* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100835530; called by muse, mutect2, varscan2
- MAP1B | c.3181C>T p.Q1061* | Nonsense Mutation (SNP) | VAF 124/394 reads (31%) | catalogued as COSV99701937; called by muse, mutect2, varscan2
- MAP1B | c.5842C>T p.R1948W | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs151255965; called by muse, mutect2
- MAP7 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 156/466 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs752064195; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 97/337 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763749761, COSV99167877; called by muse, mutect2, varscan2
- MED23 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.845); catalogued as rs867369363; called by muse, mutect2, varscan2
- METTL15 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 126/489 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1056921943; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 68/256 reads (27%) | catalogued as rs780635289; called by mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 60/218 reads (28%) | catalogued as rs765803753; called by mutect2, varscan2
- MPDZ | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557951656, CM125340, COSV59948688; called by muse, mutect2, varscan2
- MROH2B | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.072); catalogued as rs1235119079; called by muse, mutect2, varscan2
- MUC22 | c.4607C>T p.T1536M | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1462564375; called by muse, mutect2, varscan2
- MYH4 | c.5398C>T p.R1800C | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770067160, COSV55111784; called by muse, mutect2
- MYO1B | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771551697, COSV100270324; called by muse, mutect2, varscan2
- NAE1 | c.620del p.K207Rfs*10 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as rs1401721531; called by mutect2, pindel, varscan2
- NBPF3 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 60/506 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59056857; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NLRP2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.436); catalogued as rs201375258; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 44/194 reads (23%) | catalogued as rs776154715; called by mutect2, varscan2
- NSD1 | c.5556del p.E1853Sfs*2 | Frame Shift Del (DEL) | VAF 147/540 reads (27%) | catalogued as COSV61774471; called by mutect2, pindel, varscan2
- NUSAP1 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs373731616; called by muse, mutect2
- PCDHB5 | c.1967C>T p.T656M | Missense Mutation (SNP) | VAF 15/582 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.408); catalogued as COSV99169335; called by muse, mutect2
- PCDHGA5 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 91/347 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1014933070, COSV53982321; called by muse, mutect2, varscan2
- PCSK2 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 63/257 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1211284282; called by muse, mutect2, varscan2
- PCSK4 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1163487103; called by muse, mutect2, varscan2
- PDLIM4 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 60/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766274745; called by muse, mutect2, varscan2
- PHAX | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 85/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370070252; called by muse, mutect2, varscan2
- PKHD1L1 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as rs1210828715; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 58/399 reads (15%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLCH2 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201911914; called by muse, mutect2, varscan2
- PLEC | c.5885C>T p.A1962V (on ENST00000322810 / NM_201380.4; = p.A1852V on NM_000445.5) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.965); catalogued as rs781844059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA5 | c.2995del p.T999Lfs*17 | Frame Shift Del (DEL) | VAF 46/150 reads (31%) | catalogued as rs759995048, COSV54701412; called by mutect2, varscan2
- PLEKHA6 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1196925697; called by muse, mutect2, varscan2
- PLEKHF1 | c.244del p.L82Wfs*20 | Frame Shift Del (DEL) | VAF 159/530 reads (30%) | catalogued as COSV101460749; called by mutect2, pindel, varscan2
- PLXNA3 | c.4046C>T p.T1349M | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139379622; called by muse, mutect2, varscan2
- PLXNB2 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs1569172847; called by muse, mutect2, varscan2
- PNP | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 102/424 reads (24%) | catalogued as rs754734713, CM119902, COSV104422171; called by muse, mutect2, varscan2
- PRKCB | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 188/590 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100332094; called by muse, mutect2, varscan2
- PRR14L | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs1484673500; called by muse, mutect2, varscan2
- PRRC2B | c.6322G>C p.A2108P | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs574008495; called by muse, mutect2, varscan2
- PSMF1 | c.788del p.P263Rfs*75 | Frame Shift Del (DEL) | VAF 74/306 reads (24%) | catalogued as COSV55674478; called by mutect2, pindel, varscan2
- QRICH2 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 174/690 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs148029652, COSV53158517; called by muse, mutect2, varscan2
- QTRT1 | c.781del p.V261Lfs*8 | Frame Shift Del (DEL) | VAF 36/119 reads (30%) | catalogued as COSV51552974; called by mutect2, pindel, varscan2
- RAB12 | c.515del p.K172Sfs*27 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs1348000203; called by mutect2, pindel, varscan2
- RABL2B | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1555916508; called by muse, mutect2, varscan2
- RNF113B | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs1413114605; called by muse, mutect2
- RPL17-C18orf32 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs1255028692; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 130/263 reads (49%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.4194dup p.P1401Sfs*24 | Frame Shift Ins (INS) | VAF 45/172 reads (26%) | catalogued as rs762997008; called by mutect2, varscan2
- RTKN2 | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs367605349; called by muse, mutect2
- SCAF11 | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs200035348; called by muse, mutect2, varscan2
- SDK2 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs139022524; called by muse, mutect2, varscan2
- SEC23IP | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs763280855; called by muse, mutect2
- SEMA5B | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200086315; called by muse, mutect2, varscan2
- SFI1 | c.3549G>A p.W1183* (on ENST00000400288 / NM_001007467.3; = p.W1152* on NM_014775.4) | Nonsense Mutation (SNP) | VAF 16/268 reads (6%) | catalogued as rs1298693469; called by muse, mutect2
- SKIV2L | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs754925913, COSV61714351; called by muse, mutect2, varscan2
- SLA | c.122del p.P41Rfs*11 (on ENST00000338087 / NM_001045556.3; = p.P81Rfs*11 on NM_006748.4) | Frame Shift Del (DEL) | VAF 47/226 reads (21%) | catalogued as rs1564119242; called by mutect2, pindel, varscan2
- SLC11A1 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1162559913; called by muse, mutect2, varscan2
- SLC25A2 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 148/568 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53404929; called by muse, mutect2
- SLC26A8 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 67/229 reads (29%) | catalogued as rs1346725120, COSV62885355; called by muse, mutect2, varscan2
- SLC4A9 | c.622dup p.L208Pfs*18 (on ENST00000507527 / NM_001258428.2; = p.L184Pfs*18 on NM_031467.3) | Frame Shift Ins (INS) | VAF 85/328 reads (26%) | catalogued as rs747776691; called by mutect2, pindel, varscan2
- SLFN12 | c.555del p.F185Lfs*12 | Frame Shift Del (DEL) | VAF 38/178 reads (21%) | catalogued as rs747319777; called by mutect2, varscan2
- SLIRP | c.212_214del p.E71del | In Frame Del (DEL) | VAF 72/311 reads (23%) | catalogued as rs761090685; called by pindel, varscan2
- SRCAP | c.8306A>G p.Q2769R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.901); catalogued as rs1488695792, COSV52670054; called by mutect2, varscan2
- ST8SIA5 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 59/193 reads (31%) | PolyPhen possibly damaging (0.773); catalogued as rs971201898; called by muse, mutect2, varscan2
- STUB1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs145094142; called by muse, mutect2, varscan2
- STXBP1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 82/652 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239532436; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAS1R3 | c.1812del p.L606Wfs*43 | Frame Shift Del (DEL) | VAF 49/200 reads (25%) | catalogued as rs777573279, COSV100229689; called by mutect2, pindel, varscan2
- TBC1D10C | c.960del p.A321Rfs*100 | Frame Shift Del (DEL) | VAF 33/110 reads (30%) | catalogued as rs751687887; called by mutect2, pindel, varscan2
- TEP1 | c.5252G>A p.R1751Q | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs773475088, COSV99402733, COSV99403195; called by muse, mutect2
- THSD7A | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1156455476, COSV101448510, COSV101448919, COSV70265909; called by muse, mutect2, varscan2
- TLE4 | c.958G>A p.V320I | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.193); catalogued as rs761883732, COSV54629888, COSV54635624; called by muse, mutect2, varscan2
- TMEM132A | c.1480del p.L494Cfs*82 (on ENST00000453848 / NM_178031.3; = p.L495Cfs*82 on NM_017870.4) | Frame Shift Del (DEL) | VAF 81/324 reads (25%) | catalogued as COSV50001098; called by mutect2, pindel, varscan2
- TMIGD2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as rs575279420; called by muse, mutect2, varscan2
- TNRC6C | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 127/465 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755847008, COSV56944418, COSV56951868; called by muse, mutect2, varscan2
- TRO | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 104/369 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs945837385; called by muse, mutect2, varscan2
- TSPAN11 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs142835332; called by muse, mutect2, varscan2
- TTC6 | c.2997del p.D1000Tfs*2 | Frame Shift Del (DEL) | VAF 60/173 reads (35%) | catalogued as rs767436917; called by mutect2, varscan2
- TTLL2 | c.538del p.L180* | Frame Shift Del (DEL) | VAF 77/289 reads (27%) | catalogued as rs1371381574; called by mutect2, pindel, varscan2
- TTN | c.99136C>G p.L33046V (on ENST00000591111; = p.L25622V on NM_003319.4) | Missense Mutation (SNP) | VAF 63/189 reads (33%) | PolyPhen probably damaging (0.996); catalogued as COSV60089219, COSV60141384; called by muse, mutect2, varscan2
- TYMS | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759853185; called by muse, mutect2, varscan2
- U2SURP | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.281); catalogued as rs1301908368, COSV67531918; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 100/357 reads (28%) | catalogued as rs763652408; called by mutect2, varscan2
- UBTF | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57189090; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 50/203 reads (25%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- VPS35L | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766501575; called by muse, mutect2, varscan2
- WDFY3 | c.3791G>A p.R1264H | Missense Mutation (SNP) | VAF 81/274 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1449278651; called by muse, mutect2, varscan2
- WDHD1 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1020070355; called by muse, mutect2, varscan2
- WDR90 | c.2728G>A p.V910M | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs746408479, COSV104395989; called by muse, mutect2, varscan2
- WNT4 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs773957208, COSV99268697; called by muse, mutect2, varscan2
- ZNF157 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs758553770; called by muse, mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 21/204 reads (10%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF335 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747623703; called by muse, varscan2
- ZNF608 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771416896, COSV60436222; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 76/276 reads (28%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF696 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs1464302755; called by muse, mutect2, varscan2
- ZNF777 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs140558393; called by muse, mutect2, varscan2
- ZNHIT1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs764694500, COSV56185475; called by muse, mutect2, varscan2
- ZSWIM2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs376901560, COSV99719772; called by muse, varscan2
- ABCA5 | c.3590del p.N1197Mfs*13 | Frame Shift Del (DEL) | VAF 49/249 reads (20%) | called by mutect2, pindel, varscan2
- ACOXL | c.1389_1391del p.E463del (on ENST00000389811 / NM_001371254.1; = p.E433del on NM_001142807.4) | In Frame Del (DEL) | VAF 76/260 reads (29%) | called by pindel, varscan2
- ADAM18 | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAM19 | c.631T>C p.Y211H | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS6 | c.2074G>T p.G692C | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADSS2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- AKR1D1 | c.19dup p.S7Kfs*8 | Frame Shift Ins (INS) | VAF 60/277 reads (22%) | called by mutect2, pindel, varscan2
- ALOX15B | c.709T>C p.F237L | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ALPG | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- ARHGAP21 | c.382A>G p.N128D | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF12 | c.3251C>T p.T1084I | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARL6IP5 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- ARMH1 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 52/532 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- ASB11 | c.95del p.L32Wfs*4 | Frame Shift Del (DEL) | VAF 50/213 reads (23%) | called by mutect2, pindel, varscan2
- ATIC | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 128/542 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- ATP11A | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- B4GALT2 | c.-52G>A | Splice Region (SNP) | VAF 18/78 reads (23%) | called by muse, varscan2
- BARX1 | c.302T>C p.L101S | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BEST1 | c.446dup p.R150Afs*82 | Frame Shift Ins (INS) | VAF 55/218 reads (25%) | called by mutect2, pindel, varscan2
- BNIPL | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRWD3 | c.31+1G>A p.X11_splice | Splice Site (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- C11orf95 | c.1769T>C p.L590P | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C3 | c.4916A>G p.D1639G | Missense Mutation (SNP) | VAF 124/467 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C4orf19 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CACNA1A | c.2801G>T p.R934L | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CASC3 | c.1996T>C p.Y666H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASP4 | c.252dup p.N85Qfs*2 | Frame Shift Ins (INS) | VAF 52/178 reads (29%) | called by mutect2, pindel, varscan2
- CATSPER2 | c.1226A>G p.E409G (on ENST00000321596 / NM_001282309.3; = p.E411G on NM_172095.4) | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CBX2 | c.1196C>G p.A399G | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC160 | c.51del p.F17Lfs*7 | Frame Shift Del (DEL) | VAF 37/168 reads (22%) | called by mutect2, pindel, varscan2
- CCDC17 | c.1856del p.P619Qfs*2 | Frame Shift Del (DEL) | VAF 58/248 reads (23%) | called by mutect2, pindel, varscan2
- CCDC27 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCL11 | c.201dup p.L68Tfs*37 | Frame Shift Ins (INS) | VAF 72/288 reads (25%) | called by mutect2, pindel, varscan2
- CFAP61 | c.1085G>C p.S362T | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIC | c.1526del p.P509Hfs*14 | Frame Shift Del (DEL) | VAF 120/414 reads (29%) | called by mutect2, pindel, varscan2
- CKAP5 | c.876del p.K292Nfs*12 | Frame Shift Del (DEL) | VAF 30/151 reads (20%) | called by mutect2, varscan2
- COL21A1 | c.2090del p.K697Rfs*63 | Frame Shift Del (DEL) | VAF 88/371 reads (24%) | called by mutect2, pindel, varscan2
- COLEC11 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 118/410 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CRACD | c.2250G>A p.M750I | Missense Mutation (SNP) | VAF 111/379 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CREB5 | c.1463T>C p.V488A (on ENST00000357727 / NM_182898.4; = p.V481A on NM_004904.3) | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); called by muse, varscan2
- CTNND2 | c.1415del p.T472Kfs*84 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel
- DEUP1 | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMRT3 | c.966del p.I323Sfs*18 | Frame Shift Del (DEL) | VAF 107/379 reads (28%) | called by mutect2, pindel, varscan2
- DMTN | c.364del p.R122Gfs*109 | Frame Shift Del (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- DPM3 | c.-31-5_-31-3del | Splice Region (DEL) | VAF 123/415 reads (30%) | called by pindel, varscan2
- DRAM1 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- EFHC1 | c.1221del p.D408Tfs*7 | Frame Shift Del (DEL) | VAF 126/530 reads (24%) | called by pindel, varscan2
- EHBP1L1 | c.3301-2A>G p.X1101_splice | Splice Site (SNP) | VAF 70/266 reads (26%) | called by muse, mutect2, varscan2
- EHMT2 | c.3198-1G>T p.X1066_splice | Splice Site (SNP) | VAF 109/370 reads (29%) | called by muse, mutect2, varscan2
- EPHA2 | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- EPPK1 | c.5804C>T p.A1935V | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- EPS15 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPX | c.786del p.C263Afs*140 | Frame Shift Del (DEL) | VAF 142/457 reads (31%) | called by mutect2, pindel, varscan2
- ERBB3 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 150/490 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, varscan2
- EXOC8 | c.386del p.G129Afs*61 | Frame Shift Del (DEL) | VAF 77/268 reads (29%) | called by mutect2, pindel, varscan2
- FAHD2A | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAM187A | c.531del p.C178Vfs*63 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- FBLN2 | c.1018C>A p.L340I | Missense Mutation (SNP) | VAF 140/532 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FBRSL1 | c.183_189del p.T63Vfs*38 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- FGFR4 | c.1703del p.P568Qfs*53 | Frame Shift Del (DEL) | VAF 28/121 reads (23%) | called by mutect2, pindel, varscan2
- FLNA | c.7467del p.M2490Wfs*46 (on ENST00000369850 / NM_001110556.2; = p.M2482Wfs*46 on NM_001456.3) | Frame Shift Del (DEL) | VAF 128/496 reads (26%) | called by mutect2, pindel, varscan2
- FPGS | c.1218del p.E407Rfs*19 | Frame Shift Del (DEL) | VAF 50/490 reads (10%) | called by mutect2, pindel
- FRAS1 | c.5857A>G p.R1953G | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- GAN | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 145/566 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- GFI1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 109/437 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA3 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 22/622 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.407); called by muse, mutect2
- GLRX2 | c.472del p.S158Vfs*22 (on ENST00000367439 / NM_197962.3; = p.S159Vfs*22 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, varscan2
- GRID1 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 137/447 reads (31%) | called by muse, mutect2, varscan2
- GRIN2D | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRSF1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 113/414 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAPLN4 | c.802A>G p.T268A | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- HAUS1 | c.835T>C p.*279Rext*10 | Nonstop Mutation (SNP) | VAF 43/155 reads (28%) | called by muse, mutect2, varscan2
- HDAC11 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 68/278 reads (24%) | called by mutect2, pindel, varscan2
- HERC1 | c.8641A>G p.K2881E | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HMCN1 | c.1000dup p.T334Nfs*25 | Frame Shift Ins (INS) | VAF 107/436 reads (25%) | called by mutect2, varscan2
- HSPB8 | c.306dup p.S103Ffs*2 | Frame Shift Ins (INS) | VAF 105/388 reads (27%) | called by mutect2, pindel, varscan2
- IGLON5 | c.11dup p.A5Cfs*42 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | called by mutect2, varscan2
- ITGA2B | c.1122del p.S375Afs*4 | Frame Shift Del (DEL) | VAF 38/310 reads (12%) | called by pindel, varscan2
- ITPRIPL2 | c.189_191del p.L64del | In Frame Del (DEL) | VAF 11/57 reads (19%) | called by pindel, varscan2
- IVD | c.1279T>C p.*427Qext*2 (on ENST00000651168; = p.*424Qext*2 on NM_002225.5 and 5 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 152/563 reads (27%) | called by muse, mutect2, varscan2
- KCNV2 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 104/372 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- KCP | c.833C>T p.A278V (on ENST00000620378; = p.A335V on NM_001366122.1) | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KIAA2013 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KIDINS220 | c.4417del p.L1473Wfs*35 | Frame Shift Del (DEL) | VAF 58/197 reads (29%) | called by mutect2, pindel, varscan2
- KIF26B | c.5503del p.A1835Pfs*41 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by mutect2, pindel
- KIF5C | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLF2 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- KLHL34 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- KLHL42 | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KLK12 | c.734T>C p.M245T | Missense Mutation (SNP) | VAF 229/680 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KMT2B | c.2958C>G p.D986E | Missense Mutation (SNP) | VAF 71/206 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT83 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 198/687 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LEKR1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRFN1 | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LYSMD1 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, varscan2
- MAP3K10 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MAP3K13 | c.992_993del p.S331* | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by pindel, varscan2
- MAP4K4 | c.3248G>T p.R1083M (on ENST00000347699 / NM_001242559.2; = p.R1001M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED12 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- MED12 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 152/536 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED15 | c.2309C>A p.T770N (on ENST00000263205 / NM_001003891.3; = p.T730N on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- METTL4 | c.256T>G p.F86V | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MIER1 | c.1159A>G p.N387D (on ENST00000355356 / NM_001077701.3; = p.N404D on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MORC2 | c.1960C>A p.P654T (on ENST00000397641 / NM_001303256.3; = p.P592T on NM_014941.3) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MRPS18B | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MSX1 | c.755dup p.L253Pfs*87 | Frame Shift Ins (INS) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
- MTBP | c.2516C>T p.T839I | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MTOR | c.266C>A p.A89D | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MYL7 | c.194-6del | Splice Region (DEL) | VAF 30/133 reads (23%) | called by mutect2, pindel
- MYO15B | c.2621G>A p.C874Y | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MYO3A | c.3923C>T p.S1308F | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NANOGNB | c.242del p.N81Tfs*28 | Frame Shift Del (DEL) | VAF 122/450 reads (27%) | called by mutect2, pindel, varscan2
- NAP1L1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- NCOR2 | c.1056-1G>A p.X352_splice | Splice Site (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- NELL1 | c.1544G>T p.C515F | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFX1 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NKX3-1 | c.662del p.P221Hfs*65 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- NUP210L | c.2877del p.F959Lfs*32 | Frame Shift Del (DEL) | VAF 52/245 reads (21%) | called by pindel, varscan2
- NYAP1 | c.1359del p.K454Rfs*16 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- OR52E6 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52M1 | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5P3 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 95/402 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RX2 | c.314del p.X105_splice | Splice Site (DEL) | VAF 16/64 reads (25%) | called by mutect2, varscan2
- PAPPA | c.3341del p.K1114Sfs*19 | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | called by mutect2, varscan2
- PAWR | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAX7 | c.906del p.Y303Tfs*64 | Frame Shift Del (DEL) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- PCDHB5 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 210/729 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE6C | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 73/495 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PDXDC1 | c.813-1G>A p.X271_splice | Splice Site (SNP) | VAF 56/472 reads (12%) | called by muse, mutect2, varscan2
- PIM3 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 82/340 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PITPNM1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCD3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.306); called by muse, mutect2
- PLPPR2 | c.365del p.P122Qfs*29 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- POTEG | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 114/738 reads (15%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); called by muse, varscan2
- PRKCA | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- PRKCSH | c.196+2T>C p.X66_splice | Splice Site (SNP) | VAF 115/431 reads (27%) | called by muse, mutect2, varscan2
- PRR12 | c.3344C>T p.A1115V (on ENST00000615927; = p.A1936V on NM_020719.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- PTPRM | c.1200G>T p.W400C | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAD9B | c.1126-8_1126-1delinsTTTTTTTT p.X376_splice | Splice Site (ONP) | VAF 12/148 reads (8%) | called by mutect2*, pindel
- RBCK1 | c.1229A>G p.N410S (on ENST00000356286 / NM_031229.4; = p.N368S on NM_006462.6) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- SAFB2 | c.2417G>A p.G806D | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SCN1B | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.483); called by muse, mutect2
- SDK1 | c.4440del p.R1481Efs*10 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- SEC23B | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2
- SFRP2 | c.439del p.Q147Rfs*39 | Frame Shift Del (DEL) | VAF 53/204 reads (26%) | called by mutect2, pindel, varscan2
- SHANK3 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- SIRT1 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 109/381 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SIX5 | c.1026del p.V343Sfs*124 | Frame Shift Del (DEL) | VAF 69/215 reads (32%) | called by mutect2, pindel, varscan2
- SMTN | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPRYD7 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SRGAP1 | c.2567del p.P856Lfs*3 | Frame Shift Del (DEL) | VAF 12/140 reads (9%) | called by mutect2, pindel
- SULF2 | c.497del p.N166Tfs*14 | Frame Shift Del (DEL) | VAF 81/329 reads (25%) | called by mutect2, pindel, varscan2
- SYN1 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 184/686 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM1 | c.5861G>A p.G1954D | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEPSIN | c.686del p.G229Vfs*12 | Frame Shift Del (DEL) | VAF 43/149 reads (29%) | called by mutect2, pindel, varscan2
- THEMIS2 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TLN2 | c.4246G>A p.A1416T | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- TMEFF2 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TMEM121 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TMEM156 | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 131/462 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TNFRSF10A | c.1012C>T p.L338= | Splice Region (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- TNXB | c.5486A>G p.E1829G (on ENST00000647633; = p.E1582G on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- TPBG | c.898T>C p.C300R | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TPCN2 | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- TPTE | c.1540G>T p.E514* (on ENST00000618007 / NM_199261.4; = p.E496* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 62/337 reads (18%) | called by muse, mutect2, varscan2
- TRERF1 | c.1830del p.S611Pfs*104 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- TTC6 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- USH2A | c.13910del p.P4637Lfs*41 | Frame Shift Del (DEL) | VAF 33/248 reads (13%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 67/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZFHX2 | c.2387del p.G796Vfs*128 | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9379A>C p.T3127P | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ZNF214 | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ZNF226 | c.2171A>C p.E724A | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF263 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 13/314 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- ZNF292 | c.2639dup p.N880Kfs*7 | Frame Shift Ins (INS) | VAF 50/174 reads (29%) | called by mutect2, pindel, varscan2
- ZNF433 | c.148T>C p.W50R | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF572 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF618 | c.345del p.A116Rfs*25 | Frame Shift Del (DEL) | VAF 93/298 reads (31%) | called by mutect2, pindel, varscan2
- ZNF641 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF862 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.019); called by muse, mutect2
- ABI3 | c.21G>A p.L7= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- ACACB | c.5538C>T p.H1846= | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as rs1381732527; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2232C>T p.S744= | Silent (SNP) | VAF 125/456 reads (27%) | catalogued as rs1026154461; called by muse, mutect2, varscan2
- ADGB | c.2727A>T p.A909= | Silent (SNP) | VAF 66/293 reads (23%) | called by muse, mutect2, varscan2
- AHSA1 | c.396C>T p.L132= | Silent (SNP) | VAF 76/353 reads (22%) | catalogued as rs752878411, COSV53631915; called by muse, mutect2, varscan2
- AP002512.3 | c.537C>T p.N179= | Silent (SNP) | VAF 96/363 reads (26%) | catalogued as rs749194186, COSV54406835; called by muse, mutect2, varscan2
- ARHGEF17 | c.4614C>T p.D1538= | Silent (SNP) | VAF 93/299 reads (31%) | catalogued as rs1428022613; called by muse, mutect2, varscan2
- ARHGEF9 | c.951G>A p.S317= | Silent (SNP) | VAF 127/398 reads (32%) | catalogued as rs1556347447, COSV53637680; called by muse, mutect2, varscan2
- C1QTNF7 | c.444C>T p.S148= | Silent (SNP) | VAF 97/330 reads (29%) | catalogued as rs556312158, COSV99764988; called by muse, mutect2, varscan2
- CACNA1A | c.3051C>T p.Y1017= | Silent (SNP) | VAF 136/443 reads (31%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2064C>T p.C688= | Silent (SNP) | VAF 127/491 reads (26%) | catalogued as rs542437102; called by muse, mutect2, varscan2
- CARD10 | c.2682C>A p.A894= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs764508252; called by muse, mutect2, varscan2
- CCDC168 | c.12936G>A p.G4312= | Silent (SNP) | VAF 76/274 reads (28%) | catalogued as COSV59419019; called by muse, varscan2
- CCDC97 | c.168C>T p.S56= | Silent (SNP) | VAF 100/376 reads (27%) | catalogued as rs761392998; called by muse, mutect2, varscan2
- CCNL1 | c.636A>G p.L212= | Silent (SNP) | VAF 62/296 reads (21%) | called by muse, mutect2, varscan2
- CD14 | c.28C>T p.L10= | Silent (SNP) | VAF 66/229 reads (29%) | catalogued as rs766163310; called by muse, mutect2, varscan2
- CD276 | c.1119G>A p.L373= (on ENST00000318443 / NM_001024736.2; = p.L155= on NM_025240.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/264 reads (6%) | called by muse, mutect2
- CD33 | c.108C>T p.C36= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as rs745860162, COSV51802496; called by muse, mutect2, varscan2
- CELSR1 | c.7791C>T p.Y2597= | Silent (SNP) | VAF 47/178 reads (26%) | catalogued as rs553683353; called by muse, mutect2, varscan2
- CEP76 | c.1971G>A p.S657= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as rs1430656417; called by muse, mutect2, varscan2
- CHD7 | c.8610G>A p.A2870= | Silent (SNP) | VAF 26/255 reads (10%) | catalogued as rs375459176, COSV71107296; ClinVar: likely benign; called by muse, varscan2
- CLCN2 | c.1290C>T p.N430= | Silent (SNP) | VAF 32/501 reads (6%) | catalogued as rs185438143, COSV55603257; called by muse, mutect2
- COL24A1 | c.3966C>T p.G1322= | Silent (SNP) | VAF 64/156 reads (41%) | called by muse, mutect2, varscan2
- CPNE7 | c.678G>A p.S226= | Silent (SNP) | VAF 51/162 reads (31%) | catalogued as rs145150175; called by muse, mutect2, varscan2
- CRYBA1 | c.429C>T p.D143= | Silent (SNP) | VAF 79/269 reads (29%) | catalogued as rs774889777; called by muse, mutect2, varscan2
- CYB5R4 | c.870G>A p.T290= | Silent (SNP) | VAF 36/257 reads (14%) | catalogued as rs758938300, COSV63751394; called by muse, mutect2, varscan2
- DCAF15 | c.1212G>C p.P404= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV54328284; called by muse, mutect2, varscan2
- DGCR2 | c.312G>A p.Q104= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs575592075; called by muse, mutect2, varscan2
- DHTKD1 | c.864G>A p.S288= | Silent (SNP) | VAF 140/458 reads (31%) | catalogued as rs1409120999, COSV99535866; called by muse, varscan2
- DMD | c.2505C>T p.F835= | Silent (SNP) | VAF 184/614 reads (30%) | catalogued as rs771147195; called by muse, mutect2, varscan2
- DNAH5 | c.9228T>C p.S3076= | Silent (SNP) | VAF 123/462 reads (27%) | called by muse, mutect2, varscan2
- DNAJC14 | c.1570C>T p.L524= | Silent (SNP) | VAF 90/324 reads (28%) | catalogued as rs1343238038; called by muse, mutect2, varscan2
- DTX1 | c.498C>G p.R166= | Silent (SNP) | VAF 61/284 reads (21%) | called by muse, mutect2, varscan2
- DUSP8 | c.1656C>T p.G552= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs745364148; called by muse, varscan2
- EMB | c.27G>A p.E9= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, varscan2
- ERBB2 | c.2980T>C p.L994= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- F7 | c.795C>T p.I265= | Silent (SNP) | VAF 46/175 reads (26%) | catalogued as rs568985630, COSV60645321; called by muse, mutect2, varscan2
- FAM124A | c.609G>A p.A203= (on ENST00000322475 / NM_001242312.2; = p.A239= on NM_145019.4) | Silent (SNP) | VAF 19/452 reads (4%) | catalogued as COSV54476318; called by muse, mutect2
- FAT1 | c.12846C>T p.P4282= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs1388880480, COSV71673902; called by muse, mutect2, varscan2
- FGFRL1 | c.916C>T p.L306= | Silent (SNP) | VAF 40/288 reads (14%) | called by muse, mutect2, varscan2
- FLT3 | c.2916G>A p.R972= | Silent (SNP) | VAF 105/420 reads (25%) | called by muse, mutect2, varscan2
- FRMD1 | c.1182C>T p.G394= | Silent (SNP) | VAF 106/414 reads (26%) | called by muse, mutect2, varscan2
- GABRR2 | c.1035C>T p.V345= | Silent (SNP) | VAF 74/256 reads (29%) | catalogued as rs766246867, COSV101298963; called by muse, varscan2
- GMEB1 | c.177G>T p.S59= | Silent (SNP) | VAF 60/254 reads (24%) | called by muse, mutect2, varscan2
- GOLGA6D | c.642C>T p.H214= | Silent (SNP) | VAF 79/567 reads (14%) | catalogued as rs757580510, COSV101461797; called by muse, mutect2, varscan2
- GPI | c.1227G>A p.P409= | Silent (SNP) | VAF 127/473 reads (27%) | catalogued as rs774225651; called by muse, mutect2, varscan2
- GPR149 | c.819C>T p.T273= | Silent (SNP) | VAF 66/216 reads (31%) | catalogued as rs532618344; called by muse, mutect2, varscan2
- GPR150 | c.1035C>T p.S345= | Silent (SNP) | VAF 179/477 reads (38%) | called by muse, mutect2, varscan2
- GTF2IRD2B | c.1845C>T p.S615= | Silent (SNP) | VAF 112/411 reads (27%) | catalogued as rs1554532763, COSV57030698; called by muse, mutect2, varscan2
- HECW2 | c.1983C>A p.S661= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV53659040; called by muse, mutect2, varscan2
- HIC2 | c.474G>C p.R158= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs567593955, COSV68041738; called by muse, mutect2, varscan2
- HPR | c.732T>G p.P244= | Silent (SNP) | VAF 139/497 reads (28%) | called by muse, mutect2, varscan2
- IL15RA | c.744G>A p.P248= | Silent (SNP) | VAF 107/402 reads (27%) | catalogued as rs778675420, COSV66093056; called by muse, mutect2, varscan2
- IMPA2 | c.822T>C p.A274= | Silent (SNP) | VAF 76/324 reads (23%) | called by muse, mutect2, varscan2
- IQCE | c.585G>A p.T195= | Silent (SNP) | VAF 50/233 reads (21%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1263C>T p.A421= | Silent (SNP) | VAF 68/264 reads (26%) | catalogued as rs773930187, COSV53822137; called by muse, mutect2, varscan2
- JAM3 | c.61C>T p.L21= | Silent (SNP) | VAF 45/459 reads (10%) | catalogued as COSV54455136; called by muse, mutect2
- JPH2 | c.1125C>T p.R375= | Silent (SNP) | VAF 115/406 reads (28%) | catalogued as COSV65903554, COSV65904542; called by muse, varscan2
- JPH2 | c.993G>A p.L331= | Silent (SNP) | VAF 138/443 reads (31%) | called by muse, varscan2
- KEAP1 | c.975C>T p.G325= | Silent (SNP) | VAF 55/206 reads (27%) | called by muse, mutect2, varscan2
- KIAA0513 | c.879G>A p.T293= | Silent (SNP) | VAF 62/324 reads (19%) | catalogued as rs758251335, COSV50744048; called by muse, mutect2, varscan2
- KLRG2 | c.852A>G p.S284= | Silent (SNP) | VAF 87/278 reads (31%) | called by muse, mutect2, varscan2
- KRT8 | c.1182G>T p.L394= | Silent (SNP) | VAF 173/646 reads (27%) | called by muse, mutect2, varscan2
- LGALS3BP | c.342G>A p.R114= | Silent (SNP) | VAF 59/238 reads (25%) | called by muse, mutect2, varscan2
- MDGA1 | c.2238G>A p.P746= | Silent (SNP) | VAF 68/291 reads (23%) | catalogued as rs769112830, COSV51798717; called by muse, mutect2, varscan2
- MYO7A | c.3120G>A p.A1040= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs782029820, COSV68686379, COSV68686875; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAPA | c.135C>T p.Y45= | Silent (SNP) | VAF 133/483 reads (28%) | catalogued as rs1382682357, COSV54548563; called by muse, varscan2
- NCF2 | c.516T>C p.Y172= | Silent (SNP) | VAF 174/679 reads (26%) | called by muse, mutect2, varscan2
- NCSTN | c.2109G>A p.E703= | Silent (SNP) | VAF 183/658 reads (28%) | catalogued as rs530442532; called by muse, mutect2, varscan2
- NEUROG3 | c.444G>A p.A148= | Silent (SNP) | VAF 16/315 reads (5%) | called by muse, mutect2
- NOX5 | c.1134C>G p.L378= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs1227813483, COSV99533231; called by muse, mutect2, varscan2
- NPY2R | c.570G>A p.S190= | Silent (SNP) | VAF 81/270 reads (30%) | catalogued as rs375788979, COSV100279426; called by muse, mutect2, varscan2
- NTPCR | c.168C>T p.S56= | Silent (SNP) | VAF 119/511 reads (23%) | catalogued as rs754135675; called by muse, mutect2, varscan2
- PCDHA4 | c.1824G>A p.S608= | Silent (SNP) | VAF 14/448 reads (3%) | catalogued as COSV100793865; called by muse, mutect2
- PCDHGA4 | c.330G>A p.P110= | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs746063927; called by muse, mutect2, varscan2
- PDE4A | c.498G>A p.S166= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs202159530, COSV99533373; called by muse, mutect2, varscan2
- PGLYRP1 | c.511C>A p.R171= | Silent (SNP) | VAF 100/350 reads (29%) | catalogued as rs775379420, COSV50516925, COSV99151476; called by muse, mutect2, varscan2
- PIEZO2 | c.5349G>A p.A1783= | Silent (SNP) | VAF 72/275 reads (26%) | catalogued as rs901049706, COSV53290728; called by muse, mutect2, varscan2
- PKDREJ | c.1119C>T p.L373= | Silent (SNP) | VAF 71/235 reads (30%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3756C>T p.G1252= | Silent (SNP) | VAF 64/203 reads (32%) | catalogued as rs372288675; called by muse, mutect2, varscan2
- PLXNA2 | c.2358C>T p.N786= | Silent (SNP) | VAF 124/441 reads (28%) | catalogued as rs139151743; called by muse, mutect2, varscan2
- PRICKLE2 | c.585T>C p.G195= (on ENST00000295902; = p.G139= on NM_198859.4) | Silent (SNP) | VAF 119/417 reads (29%) | called by muse, mutect2, varscan2
- PRKX | c.273G>A p.E91= | Silent (SNP) | VAF 108/396 reads (27%) | called by muse, mutect2, varscan2
- PRSS38 | c.273T>C p.N91= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- PTPN23 | c.2829C>T p.P943= | Silent (SNP) | VAF 72/284 reads (25%) | catalogued as rs755640656; called by muse, mutect2, varscan2
- PTTG1 | c.450C>T p.D150= | Silent (SNP) | VAF 90/298 reads (30%) | catalogued as rs1802499; called by muse, mutect2, varscan2
- RADX | c.1893A>G p.P631= | Silent (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.2070C>A p.T690= | Silent (SNP) | VAF 54/176 reads (31%) | catalogued as COSV52511241; called by muse, mutect2, varscan2
- RGL4 | c.1224G>A p.P408= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as rs753458045, COSV51943036; called by muse, mutect2, varscan2
- RIN1 | c.105G>A p.L35= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1475997529; called by muse, mutect2, varscan2
- RRP15 | c.225C>T p.D75= | Silent (SNP) | VAF 43/309 reads (14%) | called by muse, mutect2, varscan2
- RTN4 | c.909G>A p.S303= | Silent (SNP) | VAF 71/300 reads (24%) | catalogued as rs781450328; called by muse, mutect2, varscan2
- RUNX1T1 | c.567G>A p.L189= (on ENST00000265814 / NM_001198628.1; = p.L162= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- SAMHD1 | c.1302T>C p.T434= | Silent (SNP) | VAF 148/538 reads (28%) | catalogued as rs747247611; called by muse, mutect2, varscan2
- SATB1 | c.1803G>A p.Q601= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs766256434, COSV100113105; called by muse, mutect2, varscan2
- SEC24B | c.2868T>G p.P956= | Silent (SNP) | VAF 101/335 reads (30%) | called by muse, mutect2, varscan2
- SETD1B | c.1803G>A p.P601= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs536807273, COSV57353100; called by mutect2, varscan2
- SH2D2A | c.702C>T p.A234= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs143292743; called by muse, mutect2
- SLC12A9 | c.1839G>A p.L613= | Silent (SNP) | VAF 66/198 reads (33%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1009C>T p.L337= | Silent (SNP) | VAF 114/409 reads (28%) | catalogued as rs762734292; called by muse, mutect2, varscan2
- SLC52A1 | c.168G>A p.A56= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs566207091, COSV99643367; called by muse, mutect2, varscan2
- SLITRK2 | c.906C>T p.S302= | Silent (SNP) | VAF 81/283 reads (29%) | catalogued as COSV59426661; called by muse, mutect2, varscan2
- SOX3 | c.780G>A p.T260= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV104423764; called by muse, mutect2, varscan2
- SPATA6L | c.759T>C p.F253= (on ENST00000461761 / NM_001353484.2; = p.F195= on NM_001039395.4 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- STARD8 | c.1605G>A p.A535= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs202070670; called by muse, mutect2, varscan2
- STS | c.1440C>T p.H480= | Silent (SNP) | VAF 36/260 reads (14%) | catalogued as rs752316082, COSV54269700; called by muse, varscan2
- SUPT20HL2 | c.804C>T p.G268= | Silent (SNP) | VAF 112/470 reads (24%) | called by muse, mutect2, varscan2
- TDRD15 | c.4584T>C p.L1528= | Silent (SNP) | VAF 75/240 reads (31%) | called by muse, mutect2, varscan2
- TFE3 | c.1611G>T p.S537= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV59947593; called by muse, mutect2, varscan2
- TLR7 | c.1332C>T p.F444= | Silent (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
- TNNI2 | c.348C>T p.R116= | Silent (SNP) | VAF 110/358 reads (31%) | catalogued as rs754006645; called by muse, mutect2, varscan2
- TNXB | c.10284G>A p.S3428= (on ENST00000647633; = p.S3181= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as rs745855356; called by muse, mutect2, varscan2
- TOLLIP | c.465C>T p.S155= | Silent (SNP) | VAF 64/235 reads (27%) | catalogued as rs377122220; called by muse, mutect2, varscan2
- TTC30A | c.450C>T p.G150= | Silent (SNP) | VAF 91/340 reads (27%) | catalogued as rs1177993075, COSV53688774; called by muse, mutect2, varscan2
- TUBG1 | c.186C>T p.P62= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as rs758153495; called by muse, mutect2, varscan2
- USP46 | c.1011T>C p.A337= | Silent (SNP) | VAF 62/204 reads (30%) | called by muse, mutect2, varscan2
- WDR3 | c.1131G>A p.E377= | Silent (SNP) | VAF 85/278 reads (31%) | called by muse, mutect2, varscan2
- ZBTB8B | c.1251C>T p.R417= | Silent (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- ZFHX3 | c.1452G>A p.E484= | Silent (SNP) | VAF 81/265 reads (31%) | catalogued as rs760050481, COSV51730802; called by muse, mutect2, varscan2
- ZNF236 | c.5349C>T p.C1783= | Silent (SNP) | VAF 54/199 reads (27%) | catalogued as rs765748896; called by muse, mutect2, varscan2
- ZNF532 | c.1224G>A p.S408= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as rs535517715, COSV60173236; called by muse, mutect2, varscan2
- ABCC6P1 | n.778del | RNA (DEL) | VAF 50/140 reads (36%) | catalogued as rs1262215572; called by mutect2, varscan2
- AC004890.2 | n.1603G>A | RNA (SNP) | VAF 70/256 reads (27%) | called by muse, mutect2, varscan2
- ADAM32 | chr8:39107680 C>T | 5'Flank (SNP) | VAF 30/102 reads (29%) | catalogued as rs552161495, COSV101165522; called by muse, mutect2, varscan2
- ADGB | c.4818+5500C>T | Intron (SNP) | VAF 82/324 reads (25%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.*27A>G | 3'UTR (SNP) | VAF 9/261 reads (3%) | catalogued as COSV58415308; called by muse, mutect2
- AGPAT4 | c.843+2348C>T | Intron (SNP) | VAF 79/286 reads (28%) | called by muse, mutect2, varscan2
- AKAP6 | c.3588+18del | Intron (DEL) | VAF 110/369 reads (30%) | catalogued as rs748601364; called by mutect2, varscan2
- AKAP8L | c.984+15C>T | Intron (SNP) | VAF 97/369 reads (26%) | catalogued as rs1277653907; called by muse, mutect2, varscan2
- ALDH5A1 | c.*23del | 3'UTR (DEL) | VAF 67/227 reads (30%) | catalogued as rs750959100; called by mutect2, pindel, varscan2
- ANKH | c.1011+14C>T | Intron (SNP) | VAF 82/293 reads (28%) | catalogued as rs370212587; called by muse, mutect2, varscan2
- AP002008.2 | n.1637G>A | RNA (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.-153C>T | 5'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs1012239949; called by muse, mutect2, varscan2
- ARPP21 | c.935+11A>T | Intron (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
- ATP6V0E2 | c.*396G>A | 3'UTR (SNP) | VAF 3/9 reads (33%) | catalogued as rs747365016, COSV101374608; called by muse, mutect2
- ATP7A | c.-21-8897C>T | Intron (SNP) | VAF 68/289 reads (24%) | called by muse, mutect2, varscan2
- ATRIP | c.*930C>T | 3'UTR (SNP) | VAF 115/439 reads (26%) | called by muse, mutect2, varscan2
- BMP7 | c.1146+53G>A | Intron (SNP) | VAF 91/332 reads (27%) | catalogued as rs780453766; called by muse, mutect2, varscan2
- C11orf65 | c.*1210del | 3'UTR (DEL) | VAF 46/194 reads (24%) | called by mutect2, varscan2
- C8orf34 | c.1549+3510del | Intron (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- CAMK2G | c.1273+695G>A | Intron (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2, varscan2
- CDH3 | c.46-16_46-15del | Intron (DEL) | VAF 68/297 reads (23%) | catalogued as rs1249715630; called by pindel, varscan2
- CELF2 | c.1076-2226G>A | Intron (SNP) | VAF 94/271 reads (35%) | called by muse, mutect2, varscan2
- CFAP20DC | chr3:58737181 del A | 3'Flank (DEL) | VAF 76/297 reads (26%) | called by pindel, varscan2
- CHD3 | c.*34G>A | 3'UTR (SNP) | VAF 98/305 reads (32%) | catalogued as rs776732938; called by muse, mutect2, varscan2
- CHRNA4 | c.-150C>T | 5'UTR (SNP) | VAF 22/71 reads (31%) | catalogued as rs1198498804; called by muse, mutect2, varscan2
- CLRN1 | c.*1153A>G | 3'UTR (SNP) | VAF 158/583 reads (27%) | called by muse, mutect2, varscan2
- CYB561A3 | c.706-35G>A | Intron (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- CYP27A1 | c.1184+26del | Intron (DEL) | VAF 141/525 reads (27%) | catalogued as rs1168265797; called by mutect2, pindel, varscan2
- DCBLD2 | c.571+70del | Intron (DEL) | VAF 38/142 reads (27%) | catalogued as rs780707032; called by mutect2, pindel, varscan2
- DDX11 | c.639-32A>C | Intron (SNP) | VAF 78/371 reads (21%) | called by muse, mutect2, varscan2
- DENND4C | c.5676-59del | Intron (DEL) | VAF 38/154 reads (25%) | catalogued as rs908487986; called by mutect2, varscan2
- DIP2A | c.2394+49del | Intron (DEL) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- DNAJC9 | c.-50C>G | 5'UTR (SNP) | VAF 26/215 reads (12%) | called by muse, mutect2, varscan2
- EPS8L1 | c.902-63C>T | Intron (SNP) | VAF 15/265 reads (6%) | catalogued as rs1168648449; called by muse, mutect2
- FTCDNL1 | c.*16C>T | 3'UTR (SNP) | VAF 80/273 reads (29%) | catalogued as rs751318718; called by muse, mutect2, varscan2
- GDAP1 | c.580-14del | Intron (DEL) | VAF 79/329 reads (24%) | catalogued as rs1563444154; called by mutect2, pindel, varscan2
- HNMT | c.137+2523C>A | Intron (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- HOXD1 | c.-94C>T | 5'UTR (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- IMPDH1 | chr7:128409839 G>T | 5'Flank (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- KRBA1 | c.466+212C>A | Intron (SNP) | VAF 12/345 reads (3%) | called by muse, mutect2
- LIMS2 | c.660+40del | Intron (DEL) | VAF 11/69 reads (16%) | catalogued as rs761585616; called by mutect2, pindel, varscan2
- LINC00544 | n.923C>T | RNA (SNP) | VAF 40/149 reads (27%) | called by muse, mutect2, varscan2
- MAGI2 | c.3706+13356G>T | Intron (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101893334 C>G | 3'Flank (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- MAPK9 | c.122+588G>A | Intron (SNP) | VAF 104/369 reads (28%) | called by muse, mutect2, varscan2
- MIR372 | n.63G>A | RNA (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+4202C>T | Intron (SNP) | VAF 71/246 reads (29%) | catalogued as rs763436109; called by muse, mutect2, varscan2
- NBPF11 | c.*167del | 3'UTR (DEL) | VAF 197/722 reads (27%) | called by mutect2, pindel, varscan2
- NSL1 | c.499+16125del | Intron (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- OBSCN | c.18662-2690A>G | Intron (SNP) | VAF 179/610 reads (29%) | called by muse, mutect2, varscan2
- OR4C4P | n.106G>T | RNA (SNP) | VAF 54/226 reads (24%) | called by muse, mutect2, varscan2
- PANK3 | c.936+422C>A | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4930C>T | Intron (SNP) | VAF 43/178 reads (24%) | catalogued as rs1408958867; called by muse, mutect2, varscan2
- PDXDC1 | c.728-26del | Intron (DEL) | VAF 80/569 reads (14%) | called by mutect2, varscan2
- PEG10 | c.*348G>A | 3'UTR (SNP) | VAF 98/388 reads (25%) | catalogued as COSV71788767; called by muse, mutect2, varscan2
- PIPSL | n.1371dup | RNA (INS) | VAF 134/516 reads (26%) | called by mutect2, pindel, varscan2
- PLOD1 | c.-33C>A | 5'UTR (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- POLR1D | c.27-12dup | Intron (INS) | VAF 40/149 reads (27%) | catalogued as rs1411951922; called by mutect2, pindel, varscan2
- PRRT1 | c.*168G>A | 3'UTR (SNP) | VAF 60/211 reads (28%) | catalogued as rs1208442444; called by muse, mutect2, varscan2
- RALGAPA2 | c.2203+2949G>A | Intron (SNP) | VAF 68/262 reads (26%) | catalogued as rs992621053; called by muse, mutect2, varscan2
- RFX4 | c.-33_-16del | 5'UTR (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- RGMA | c.130+6669A>G | Intron (SNP) | VAF 91/404 reads (23%) | called by muse, mutect2
- SDC2 | c.-41G>A | 5'UTR (SNP) | VAF 45/184 reads (24%) | called by muse, mutect2, varscan2
- SEMA6D | c.1765+22del | Intron (DEL) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- SLC26A6 | c.1530-12_1530-9del | Intron (DEL) | VAF 26/100 reads (26%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.3546+49C>T | Intron (SNP) | VAF 61/242 reads (25%) | called by muse, mutect2, varscan2
- SPOCD1 | c.2029-53G>A | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- TBC1D9B | c.2791+29A>G | Intron (SNP) | VAF 31/114 reads (27%) | catalogued as rs1485766986; called by muse, mutect2, varscan2
- TBX1 | c.*9G>A | 3'UTR (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- TCP1 | c.378-137dup | Intron (INS) | VAF 78/293 reads (27%) | catalogued as rs780928187; called by pindel, varscan2
- TCP10L3 | n.457C>T | RNA (SNP) | VAF 77/314 reads (25%) | catalogued as rs1253387821; called by muse, mutect2, varscan2
- TIMM8A | c.132+41T>A | Intron (SNP) | VAF 128/444 reads (29%) | called by muse, mutect2, varscan2
- TM2D3 | c.*15del | 3'UTR (DEL) | VAF 41/133 reads (31%) | called by mutect2, pindel, varscan2
- TPPP2 | chr14:21035849 C>T | 3'Flank (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- TRHDE | chr12:72271936 C>T | 5'Flank (SNP) | VAF 85/276 reads (31%) | catalogued as rs1229029930; called by muse, mutect2, varscan2
- UPF3A | c.*8C>T | 3'UTR (SNP) | VAF 138/485 reads (28%) | called by muse, mutect2, varscan2
- VCX | c.-45C>T | 5'UTR (SNP) | VAF 112/809 reads (14%) | called by muse, mutect2, varscan2
- WDR54 | c.-2+26del | Intron (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- WDR77 | chr1:111449380 C>T | 5'Flank (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- ZNF140 | c.-11T>G | 5'UTR (SNP) | VAF 44/190 reads (23%) | called by muse, varscan2
- ZNF271P | n.2160T>C | RNA (SNP) | VAF 92/290 reads (32%) | called by muse, varscan2
- ZNF511 | c.*913C>T | 3'UTR (SNP) | VAF 61/220 reads (28%) | catalogued as rs142257347; called by muse, mutect2, varscan2
